Surgical pathology report (de-identified scan), TCGA case TCGA-5U-AB0D, project TCGA-THYM (Thymoma), tissue source site Regina Elena National Cancer Institute, specimen TCGA-5U-AB0D-01A (Primary Tumor).

path *ICD-O-3*
Thymoma, type C 8586/3
Carcinoma, neuroendocrine NOS 8246/3
Site: Anterior mediastinum
C38.1
Q25/21/14

SURNAME and NAME :

Sex: F

BIRTH DATE

Hospital:

Department: Thoracic Surgery

Clinical informations: Mediastinal anterior neoplasia cm 12x10x5

Type of specimen: Biopsies of the mass

Microscopical description: multiple small tissue fragments, histologically characterized by a neoplastic infiltration with morphological and immunohistochemical characters (positivity for CD117 and Synaptophysin; positivity +/- for citocheratins (MNF116), negativity for CD5, CD45, CD56, TTF1, Cromogranin) indicating a poorly differentiated (neuro)endocrine carcinoma. Growth fraction, as evaluated by the KI67: 30-40% in the best evaluable areas.

Diagnosis: The anatomical location of the neoplasia and the CD117 positivity are consistent with a thymic origin of the neoplasia (Neuroendocrine thymic carcinoma according to the 2004 WHO classification).

Acceptance date:

Reporting date:

Source: NCI Genomic Data Commons file 21663541-15a9-4980-916b-ac2205dae2d5 (TCGA-5U-AB0D.D102571C-8F6B-428D-BF82-AE75DB12A16C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).